Gene-level copy-number profile of tumor specimen TCGA-29-1766-01A from TCGA case TCGA-29-1766, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Peritoneum, NOS; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 74.9 years (27,359 days).
Specimen TCGA-29-1766-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.fef20c85-59fd-4c83-a61d-e7cdc277917a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1766-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7f330761-f337-4b5d-af84-9658e399229e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,253; copy number 2: 2,652; copy number 3: 20,442; copy number 4: 17,641; copy number 5: 4,968; copy number 6: 8,754; copy number 7: 3,324; copy number 8: 408; copy number 9: 324; copy number 10: 32; copy number 12: 3; copy number 18: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1766-01A-01D-0559-01): tumor purity 0.55, ploidy 4.24, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,047 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–14,531,223, 224 genes, copy number 7 (broad region; genes not listed).
- chr3:90,030,284–198,222,513, 1,806 genes, copy number 7 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 8–9 (broad region; genes not listed).
- chr7:13,854,355–14,010,763, 4 genes, copy number 10: AC005019.2, AC005019.1, ETV1, Y_RNA.
- chr8:115,408,496–115,809,673, 1 gene, copy number 10 (within-gene range 6–10): TRPS1.
- chr10:44,712–6,879,450, 141 genes, copy number 7 (broad region; genes not listed).
- chr10:21,174,014–38,783,108, 329 genes, copy number 7 (broad region; genes not listed).
- chr10:46,337,224–52,314,507, 128 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr10:76,835,377–83,912,922, 112 genes, copy number 7 (broad region; genes not listed).
- chr12:5,948,877–6,851,292, 53 genes, copy number 7: VWF, RN7SL69P, AC005845.1, CD9, Y_RNA, ATP5MFP5, PLEKHG6, TNFRSF1A, RN7SL391P, SCNN1A, LTBR, AC005840.2, AC005840.1, SRP14P1, CD27-AS1, CD27, TAPBPL, VAMP1, AC005840.4, AC005840.3, MRPL51, NCAPD2, SCARNA10, AC006064.5, AC006064.3, GAPDH, AC006064.4, IFFO1, AC006064.1, NOP2, AC006064.6, CHD4, AC006064.2, SCARNA11, LPAR5, ACRBP, ING4, AC125494.1, ZNF384, PIANP, RNU6-781P, AC125494.3, COPS7A, AC125494.2, MLF2, PTMS, LAG3, RN7SL380P, CD4, GPR162, P3H3, GNB3, CDCA3.
- chr19:27,638,483–30,957,192, 69 genes, copy number 8–18 (broad region; genes not listed).
- chr19:47,968,046–48,391,551, 20 genes, copy number 7: BSPH1, ELSPBP1, CABP5, PLA2G4C, PLA2G4C-AS1, LIG1, AC011466.3, AC011466.2, ZSWIM9, CARD8, AC011466.4, AC011466.1, CARD8-AS1, ZNF114-AS1, ZNF114, CCDC114, EMP3, TMEM143, SYNGR4, KDELR1.
- chr20:50,429,190–51,098,845, 22 genes, copy number 7: RN7SL636P, COX6CP2, PTPN1, RN7SL672P, Y_RNA, AL133230.1, MIR645, RIPOR3, MIR1302-5, RPL36P2, RIPOR3-AS1, PARD6B, BCAS4, TMSB4XP6, ADNP, PSMD10P1, ADNP-AS1, DPM1, MOCS3, AL050404.1, KCNG1, AL121785.1.
- chr20:61,953,469–64,313,132, 138 genes, copy number 7 (broad region; genes not listed).
- chr22:20,587,496–24,270,134, 290 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
